CCDI case PBCDNW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/9ebc79f9-0ca0-405e-a5f7-29edde2faef3

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Mesenchymal chondrosarcoma: ICD-O-3 morphology code: 9240/3; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 16.9 years (6,179 days).

Biospecimens (3 samples)
- Sample 0DPE97: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPE9G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPE9M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
